Somatic mutation profile of tumor specimen TCGA-BK-A26L-01C (aliquot TCGA-BK-A26L-01C-04D-A272-09) from TCGA case TCGA-BK-A26L, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 71.2 years (26,002 days).
Specimen TCGA-BK-A26L-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85986a8e-4e34-4a7e-9913-249a31c4c1b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A26L-10A (Blood Derived Normal), aliquot TCGA-BK-A26L-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/967ecc61-583e-46f7-bc47-f9e72e8220e7

The open-access MAF lists 47 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 16, Intron 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1514G>T p.R505L (on ENST00000281708 / NM_001349798.2; = p.R425L on NM_018315.5) | Missense Mutation (SNP) | VAF 28/49 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 9/14 reads (64%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs377469652; called by muse, mutect2, varscan2
- ADGRB2 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99925561; called by muse, mutect2, varscan2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- CALN1 | c.458T>G p.I153S (on ENST00000329008 / NM_001017440.3; = p.I195S on NM_031468.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100204403; called by muse, mutect2
- EZHIP | c.1204C>T p.H402Y | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100539434; called by muse, varscan2
- HDAC8 | c.816T>A p.D272E | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101005241; called by muse, mutect2, varscan2
- IL7 | c.79T>A p.C27S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761646272; called by muse, mutect2, varscan2
- KCNK2 | c.310T>A p.S104T (on ENST00000444842 / NM_001017425.3; = p.S89T on NM_014217.4) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101221762; called by muse, mutect2
- LARS2 | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99647325; called by muse, mutect2, varscan2
- MAGEA3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV64755983; called by muse, mutect2, varscan2
- MAP3K10 | c.1580G>A p.S527N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99453858; called by muse, mutect2, varscan2
- ME2 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100360597, COSV58425335; called by muse, mutect2
- MYH7 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV100805612; called by muse, mutect2, varscan2
- PLA2G4C | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs200386711, COSV104415928; called by muse, mutect2, varscan2
- RICTOR | c.3706C>A p.P1236T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV57117269; called by muse, mutect2, varscan2
- SDK2 | c.4532C>T p.T1511M | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as rs140102684; called by muse, mutect2, varscan2
- SLC25A48 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs746170434, COSV99191925; called by muse, mutect2, varscan2
- SLC39A12 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755814869, COSV66201244, COSV66201612; called by muse, mutect2, varscan2
- STYXL2 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776784375, COSV99608457; called by muse, mutect2, varscan2
- THSD4 | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1364571014, COSV99964183; called by muse, varscan2
- TRIM23 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.142); catalogued as rs764699841, COSV99139840; called by muse, mutect2, varscan2
- YTHDC2 | c.1954A>T p.S652C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV99362823; called by muse, mutect2, varscan2
- ZGPAT | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1176701629, COSV58874264; called by muse, mutect2, varscan2
- ZIM2 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1238828956, COSV55648393; called by muse, mutect2, varscan2
- GPHN | c.1045+1G>T p.X349_splice (on ENST00000315266 / NM_001377519.1; = p.X382_splice on NM_020806.5) | Splice Site (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- RB1CC1 | c.633_634del p.H211Qfs*14 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- AP3B2 | c.3207C>T p.S1069= (on ENST00000261722; = p.S1063= on NM_004644.5) | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs540715932, COSV55607437; called by muse, mutect2, varscan2
- C15orf39 | c.1044C>G p.A348= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100641160; called by muse, mutect2, varscan2
- CR1L | c.180T>C p.Y60= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV99686712; called by muse, mutect2, varscan2
- ESRRA | c.93C>G p.T31= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs200261687, COSV50004576, COSV99134409; called by mutect2, varscan2
- GCN1 | c.69A>G p.V23= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- GRID1 | c.1614C>T p.D538= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1441235817, COSV100021404; called by muse, mutect2, varscan2
- GUCY1A2 | c.900T>C p.N300= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs535328414, COSV56489461, COSV99972307; called by mutect2, varscan2
- KLHL1 | c.237G>A p.S79= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV64770373; called by muse, mutect2
- LAMTOR5 | c.195G>T p.V65= (on ENST00000602318 / NM_001382293.1; = p.V147= on NM_006402.3) | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99862039; called by muse, mutect2, varscan2
- OR52R1 | c.714C>G p.L238= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- PTPRS | c.2730C>G p.R910= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- RND3 | c.681G>C p.S227= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs769148948, COSV55724618; called by mutect2, varscan2
- SYT2 | c.816C>T p.G272= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs746445612, COSV100937116; called by muse, mutect2, varscan2
- TBL1X | c.1731G>A p.K577= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54289338; called by muse, mutect2, varscan2
- WASHC2A | c.3543T>C p.D1181= | Silent (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- ZMYM3 | c.561A>T p.P187= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100077377; called by muse, mutect2
- ATP8A2 | c.1662+59G>A | Intron (SNP) | VAF 67/118 reads (57%) | catalogued as COSV54938762; called by muse, mutect2, varscan2
- LIN7A | c.82+1852A>G | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV99691628; called by muse, mutect2, varscan2
